Gene-level copy-number profile of tumor specimen ALCH-B4XI-TTP1-A from ALCHEMIST case ALCH-B4XI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 33.0 years (12,046 days).
Specimen ALCH-B4XI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 328153ad-c012-4674-a6f2-f64404f68fda.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/fb24f577-12f1-4aa0-a3e5-df549214c78a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 15,670; copy number 2: 36,488; copy number 3: 6,220; copy number 4: 348; copy number 5: 3; copy number 6: 8; copy number 9: 5; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 148 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr2:10,192,614–10,457,693, 8 genes (within-gene range 0–1): MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT.
- chr2:15,668,684–16,105,841, 13 genes: AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1.
- chr2:23,385,179–23,708,611, 4 genes: KLHL29, AC011239.1, AC011239.2, AC009242.1.
- chr2:218,382,029–218,405,941, 4 genes: SLC11A1, CTDSP1, AC021016.2, MIR26B.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:66,070,904–66,094,697, 2 genes (within-gene range 0–2): AC068533.1, ASL.
- chr7:66,505,155–66,592,397, 6 genes (within-gene range 0–1): AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1.
- chr9:125,372,325–125,372,766, 1 gene: AL627223.1.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr10:125,032,783–125,032,870, 1 gene (within-gene range 0–2): MIR4296.
- chr11:1,983,237–1,989,920, 1 gene (within-gene range 0–10): MRPL23-AS1.
- chr11:32,435,738–32,435,846, 1 gene (within-gene range 0–2): AL049692.6.
- chr11:57,484,534–57,515,780, 1 gene: SLC43A1.
- chr12:122,167,738–122,203,471, 2 genes: LRRC43, IL31.
- chr12:129,839,928–129,854,944, 2 genes (within-gene range 0–2): AC055717.3, AC055717.1.
- chr13:100,062,296–100,063,601, 1 gene: ASNSP3.
- chr13:113,399,610–113,453,524, 1 gene: ADPRHL1.
- chr15:25,174,927–25,257,027, 43 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:85,759,326–85,794,925, 3 genes: KLHL25, MIR1276, AC021739.1.
- chr17:2,337,498–2,381,058, 3 genes (within-gene range 0–1): SGSM2, AC006435.3, AC006435.2.
- chr17:2,689,386–3,037,741, 9 genes (within-gene range 0–1): CLUH, MIR6776, AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253, RAP1GAP2, AC015921.1.
- chr17:16,217,191–16,492,193, 15 genes (within-gene range 0–1): PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr18:94,202–94,330, 1 gene: AP001005.2.
- chr19:50,555,370–50,557,969, 1 gene (within-gene range 0–1): AC008743.1.
- chr19:54,415,219–54,436,904, 3 genes: TTYH1, AC245884.1, AC245884.9.
- chr20:58,995,185–59,007,254, 1 gene: CTSZ.
- chr21:31,559,245–31,560,487, 1 gene (within-gene range 0–2): AP000251.1.
- chr22:17,734,138–17,779,481, 3 genes: BID, MIR3198-1, LINC00528.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–1): AC016026.1, AC016026.2.
- chr22:18,422,244–18,500,594, 1 gene (within-gene range 0–4): FAM230A.
- chr22:38,056,311–38,110,684, 5 genes: PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1.
- chr22:38,130,216–38,150,612, 1 gene (within-gene range 0–1): AL022322.2.
- chr22:41,909,554–41,958,933, 5 genes: SHISA8, TNFRSF13C, MIR378I, CENPM, LINC00634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:29,088,649–29,189,643, 2 genes, copy number 5: AC105398.1, CLIP4.
- chr2:35,219,377–35,725,142, 5 genes, copy number 6: SMIM7P1, MIR548AD, RNU6-1117P, AC083939.1, MRPL50P1.
- chr11:1,947,278–1,984,522, 1 gene, copy number 10 (within-gene range 0–10): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 9: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–6: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 12,814. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
